MMRF case MMRF_1682 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/383f9e8e-7814-4e2a-a66e-1fd1f90bdf62

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Age at index: 72 years; Vital status: Dead; Days to death: 620 days (1.7 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 72.2 years (26,379 days); ISS stage: II; Days to last known disease status: 620 days (1.7 years); Days to last follow up: 620 days (1.7 years).
   Treatment given: Therapeutic agents: Bortezomib + Melphalan + Prednisone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 295 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 338 days; Days to treatment end: 447 days (1.2 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: Third line of therapy; Days to treatment start: 448 days (1.2 years); Days to treatment end: 577 days (1.6 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: Fourth line of therapy; Days to treatment start: 578 days (1.6 years); Days to treatment end: 617 days (1.7 years).
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: Fourth line of therapy; Days to treatment start: 578 days (1.6 years); Days to treatment end: 580 days (1.6 years).
   Treatment given: Therapeutic agents: Doxorubicin; Regimen or line of therapy: Fourth line of therapy; Days to treatment start: 612 days (1.7 years); Days to treatment end: 612 days (1.7 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 620.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 0 (ECOG 1): M Protein 2.57 g/dL; Immunoglobulin G 31.9 g/L; Immunoglobulin A 0.33 g/L; Immunoglobulin M 0.37 g/L; Beta 2 Microglobulin 4.7 µg/mL; Lactate Dehydrogenase 3.9 µkat/L; Hemoglobin 8.99 mmol/L; Leukocytes 6.29 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 195 ×10⁹/L; Creatinine 88.4 µmol/L; Calcium 1.85 mmol/L; Albumin 29 g/L; Total Protein 8.2 g/dL; Glucose 4.46 mmol/L; C-Reactive Protein 0.36 mg/dL.
- Day 85: M Protein 0.15 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 148 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 125 mg/dL; Immunoglobulin G 8.85 g/L; Immunoglobulin A 0.33 g/L; Immunoglobulin M 0.24 g/L; Beta 2 Microglobulin 2 µg/mL; Lactate Dehydrogenase 3.43 µkat/L; Hemoglobin 8.18 mmol/L; Leukocytes 4.67 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 205 ×10⁹/L; Creatinine 70.7 µmol/L; Calcium 2.43 mmol/L; Albumin 45 g/L; Total Protein 6.7 g/dL; Glucose 5.17 mmol/L.
- Day 211: M Protein 0.21 g/dL; Immunoglobulin G 10.5 g/L; Immunoglobulin A 0.33 g/L; Immunoglobulin M 0.24 g/L; Beta 2 Microglobulin 2.1 µg/mL; Lactate Dehydrogenase 3.65 µkat/L; Hemoglobin 8.62 mmol/L; Leukocytes 4.13 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 195 ×10⁹/L; Creatinine 72.5 µmol/L; Blood Urea Nitrogen 15.7 mmol/L; Calcium 2.2 mmol/L; Albumin 44 g/L; Total Protein 6.9 g/dL; Glucose 5.56 mmol/L.
- Day 295: M Protein 0.65 g/dL; Immunoglobulin G 12.2 g/L; Immunoglobulin A 0.33 g/L; Immunoglobulin M 0.28 g/L; Hemoglobin 8.12 mmol/L; Leukocytes 5.14 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 177 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 15 mmol/L; Calcium 2.35 mmol/L; Albumin 36 g/L; Total Protein 7.9 g/dL; Glucose 5.78 mmol/L.
- Day 367: Hemoglobin 5.46 mmol/L; Leukocytes 1.89 ×10⁹/L; Absolute Neutrophil 1.1 ×10⁹/L; Platelets 65 ×10⁹/L; Creatinine 38 µmol/L; Albumin 19 g/L; Total Protein 4.6 g/dL; Glucose 4.62 mmol/L.
- Day 477 (ECOG 1): M Protein 0.24 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 109 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 133 mg/dL; Immunoglobulin G 7.53 g/L; Immunoglobulin A 0.33 g/L; Immunoglobulin M 0.66 g/L; Beta 2 Microglobulin 2.8 µg/mL; Lactate Dehydrogenase 3.1 µkat/L; Hemoglobin 6.08 mmol/L; Leukocytes 2.32 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 83 ×10⁹/L; Creatinine 57.5 µmol/L; Blood Urea Nitrogen 11.8 mmol/L; Calcium 2.1 mmol/L; Albumin 35 g/L; Total Protein 5.6 g/dL; Glucose 5.01 mmol/L.
- Day 567 (ECOG 2): Lactate Dehydrogenase 4.98 µkat/L; Hemoglobin 6.94 mmol/L; Leukocytes 1.35 ×10⁹/L; Absolute Neutrophil 0.8 ×10⁹/L; Platelets 55 ×10⁹/L; Creatinine 74.3 µmol/L; Glucose 5.12 mmol/L.
- Day 616 (ECOG 4): Hemoglobin 5.27 mmol/L; Leukocytes 2.9 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 20 ×10⁹/L; Creatinine 221 µmol/L; Total Protein 4.5 g/dL; Glucose 4.84 mmol/L.

Other clinical attributes
- Day 0: Weight: 71 kg; Height: 155 cm.

Biospecimens (3 samples)
- Sample MMRF_1682_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 0 days.
- Sample MMRF_1682_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 0 days.
- Sample MMRF_1682_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 295 days.
